Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4821, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4821-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: GALLBLADDER, CHOLECYSTECTOMY –

ACUTE AND CHRONIC CALCULOUS CHOLECYSTITIS. NO EVIDENCE OF MALIGNANCY.

PART 2: GALLSTONES, REMOVAL –

CHOLELITHIASIS (gross diagnosis).

PART 3: LEFT KIDNEY AND LEFT ADRENAL GLAND, RESECTION –

- A. RENAL CELL CARCINOMA, CONVENTIONAL TYPE (CLEAR AND GRANULAR CELL FEATURES), EXTENSIVELY INVOLVING THE LEFT KIDNEY AND FOCALLY INVOLVING THE RENAL PELVIS (slide 3I).
- B. MAXIMAL TUMOR DIMENSION IS 11 CM.
- C. PREDOMINANT FUHRMAN NUCLEAR GRADE IS 2/4 WITH FOCAL AREA OF FUHRMAN NUCLEAR GRADE 3/4 (slide 2I), ASSOCIATED WITH FOCAL TUMOR NECROSIS.
- D. TUMOR IS CONFINED BY CAPSULE, WITH NO CARCINOMATOUS EXTRACAPSULAR EXTENSION.
- E. OCCLUSIVE CARCINOMATOUS THROMBUS WITHIN LARGE RENAL VEIN (slide 3C).
- F. URETER, PERIRENAL SOFT TISSUE AND ALL SURGICAL RESECTION MARGINS ARE BENIGN.
- G. ONE BENIGN ADRENAL GLAND AND ONE (1) BENIGN PERIRENAL HILAR LYMPH NODE.
- H. NON-NEOPLASTIC KIDNEY WITH ARTERIAL AND ARTERIOLAR SCLEROSIS, CHRONIC INTERSTITIAL INFLAMMATION AND FOCAL ACUTE TUBULITIS, WITH AGE APPROPRIATE GLOMERULAR AND TUBULOINTERSTITIAL CHRONICITY CHANGES.
- I. PATHOLOGIC STAGE: T3b, NX, MX. (See microscopic description).

PART 4: SMALL INTESTINE, SEGMENTAL RESECTION –

SEGMENT OF BENIGN SMALL INTESTINE WITH FOCAL SURGICAL DEFECT, OTHERWISE, NO SPECIFIC PATHOLOGIC ABNORMALITY. NO EVIDENCE OF MALIGNANCY.

Final Diagnosis

LUNG LEFT UPPER LOBE, FINE NEEDLE ASPIRATION BIOPSY:

- METASTATIC RENAL CELL CARCINOMA. SEE COMMENT.

Comment:

The aspirates are pauci-cellular and reveal rare small clusters of malignant epithelial cells in a background of blood. Only rare reactive bronchial cells and sparse inflammatory cells are present. The tumor cells are large with abundant granular cytoplasm and well defined cell borders. The nuclei are enlarged and mildly pleomorphic with moderately irregular contours, coarse chromatin and prominent central nucleoli. The morphologic findings are consistent with a renal cell carcinoma. To confirm the diagnosis and help exclude a primary lung tumor, we performed a panel of immunohistochemical stains on the cell block material with the following results:

Antibody	Usual reactivity	Result
CD10	Renal cell marker,	Positive
Pan-keratin	Epithelial marker	Positive
CK 7	Epithelial marker	Positive
CK 20	Epithelial marker	Negative
RCC	Renal cell marker	Negative
CD 68	Histiocyte marker	Negative
TTF-1	Pulmonary cell marker	Negative

The immunohistochemical staining pattern supports the morphologic diagnosis. Positive staining for CD10 and pan keratin with negative staining for CK 20 is consistent with renal cell carcinoma. Although CK7 is often negative in most renal cell carcinomas, positive staining can be seen in up to 1/3 of cases. Similarly, negative staining for RCC is seen in approximately 13% of cases. Negative staining for CD68 indicated the tumor cells are not reactive pulmonary macrophages which can have similar morphology in rare cases. Negative staining for TTF-1 also rules against a diagnosis of a primary lung carcinoma. Overall, based on morphology and immunohistochemical findings the final diagnosis is that of metastatic renal cell carcinoma. [REDACTED] have reviewed this case and concur with the diagnosis.

Final Diagnosis

LUNG, LEFT, NODULE, FNA:

LESS THAN OPTIMAL - SCANT CELLULARITY.
NEGATIVE FOR MALIGNANT CELLS.

HYPERCELLULAR SPECIMEN WITH REACTIVE EPITHELIAL CELLS AND BLOOD (see comment).

Comment:

Because of the minute size of the lesion and technical difficulty of this biopsy, a limited sampling was obtained. No definitive evidence of malignancy identified. Immunohistochemical stains for CD10, RCC and CD68 are non-contributory. Additional studies should be considered if clinically indicated.

Source: NCI Genomic Data Commons file acf0f2d8-1d2b-4e84-b554-6a9207b2bdb4 (TCGA-B0-4821.7BED3C94-DB26-49DD-AB93-65B6643C0643.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).